Somatic mutation profile of tumor specimen TCGA-CN-5369-01A (aliquot TCGA-CN-5369-01A-01D-1434-08) from TCGA case TCGA-CN-5369, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Hard palate; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-CN-5369-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 50d72355-3333-48c6-94f1-852575443671.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-5369-10A (Blood Derived Normal), aliquot TCGA-CN-5369-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fdd1a1cc-3ab9-4e7c-a354-12ebffd91044

The open-access MAF lists 460 somatic variants for this specimen: 354 protein-altering or splice-affecting, 99 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 277, Silent 99, Frame Shift Del 37, Nonsense Mutation 24, Splice Site 5, Intron 4, Frame Shift Ins 4, Splice Region 3, Nonstop Mutation 2, RNA 2, 5'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CASP8 | c.742C>T p.R248W (on ENST00000432109 / NM_033355.3; = p.R265W on NM_001228.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as rs17860424, CM023571, COSV51855342; ClinVar: pathogenic; called by mutect2, varscan2
- EFHC1 | c.826C>T p.R276* | Nonsense Mutation (SNP) | VAF 13/115 reads (11%) | catalogued as rs796052414, COSV100932128; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2A | c.3790C>T p.R1264* | Nonsense Mutation (SNP) | VAF 6/82 reads (7%) | hotspot (GDC flag); catalogued as rs1555039343, COSV63282990; ClinVar: pathogenic; called by muse, mutect2
- KMT2D | c.1940dup p.P648Tfs*2 | Frame Shift Ins (INS) | VAF 10/73 reads (14%) | catalogued as rs770315135; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- POMGNT1 | c.1738C>T p.R580* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs386834018, CM077960, COSV100915782; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- AASDHPPT | c.569G>A p.G190E | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1238570169, COSV99593409; called by muse, mutect2, varscan2
- ABCA13 | c.11595C>G p.F3865L | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101447167, COSV71289851; called by muse, mutect2, varscan2
- ABLIM2 | c.1213G>C p.D405H (on ENST00000341937 / NM_001130084.2; = p.D438H on NM_001130083.2) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV56407922, COSV99590383; called by muse, mutect2, varscan2
- ACADVL | c.1247C>T p.A416V | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99138811; called by muse, mutect2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 22/106 reads (21%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADCY6 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100326860; called by muse, mutect2, varscan2
- ADCY8 | c.3673T>C p.Y1225H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV99653992; called by muse, mutect2
- AEBP1 | c.2647G>C p.E883Q | Missense Mutation (SNP) | VAF 8/210 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.264); catalogued as COSV99789053; called by muse, mutect2
- AGO3 | c.2278A>G p.T760A | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1263448049, COSV55792873; called by muse, mutect2, varscan2
- AGPAT2 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs759115310, COSV100452046; called by muse, mutect2
- AHNAK | c.10468G>A p.E3490K | Missense Mutation (SNP) | VAF 7/143 reads (5%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as COSV99949297; called by muse, mutect2
- ALG13 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 30/286 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.628); catalogued as COSV99322900; called by muse, mutect2, varscan2
- ALX4 | c.1194G>A p.M398I | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1476323980, COSV100241233; called by mutect2, varscan2
- ANKIB1 | c.2413A>G p.S805G | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs775363363, COSV56059204; called by muse, mutect2, varscan2
- ANKS6 | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs758892976, COSV62050613; called by mutect2, varscan2
- AP4E1 | c.553C>T p.R185* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as rs781292684, COSV99957120; called by muse, mutect2, varscan2
- ARF6 | c.433C>G p.R145G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.014); catalogued as COSV100028491, COSV53597553; called by muse, mutect2, varscan2
- ARHGAP1 | c.52G>A p.E18K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs566681425, COSV100305649; called by muse, mutect2, varscan2
- ARHGAP44 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99311410; called by muse, mutect2, varscan2
- ARHGAP5 | c.2886A>C p.E962D | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.636); catalogued as COSV100565666; called by muse, mutect2
- ARHGEF11 | c.2898G>A p.M966I | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100168896; called by muse, mutect2
- ARHGEF4 | c.1949G>A p.R650H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as rs777849725, COSV58129090; called by muse, mutect2, varscan2
- ATAD5 | c.4040G>A p.G1347D | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768396417, COSV100430183, COSV58977489; called by muse, mutect2, varscan2
- ATP10A | c.3739A>T p.I1247F | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV100791479; called by muse, mutect2
- ATP1B1 | c.385G>A p.V129M | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as rs1251728499, COSV100891635; called by muse, mutect2
- ATP6V0A4 | c.2393G>A p.G798D | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100023601; called by muse, mutect2
- ATP7B | c.3107T>C p.V1036A | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.247); catalogued as COSV99666898; called by muse, mutect2, varscan2
- ATRX | c.3617C>G p.S1206C | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV100971333, COSV64870729; called by muse, mutect2
- ATXN7L2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1477912338, COSV63992186; called by muse, mutect2
- B3GLCT | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100587419; called by muse, mutect2
- BCAN | c.485G>A p.R162Q | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372404921; called by muse, mutect2, varscan2
- BCAR1 | c.1922del p.P641Lfs*61 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as COSV50803791; called by mutect2, pindel, varscan2
- BRWD3 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64746047; called by muse, mutect2
- BRWD3 | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.042); catalogued as COSV100956443; called by muse, mutect2
- BSN | c.9496A>G p.S3166G | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV99609616; called by muse, mutect2
- BTBD1 | c.1048C>T p.R350* | Nonsense Mutation (SNP) | VAF 49/496 reads (10%) | catalogued as rs201223863, COSV99915683; called by muse, mutect2
- C7orf31 | c.998G>A p.G333E | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275854590, COSV99384125; called by muse, mutect2
- CACNA1E | c.1842C>G p.I614M | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100704846, COSV62414577; called by mutect2, varscan2
- CATSPER4 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100128500; called by muse, mutect2, varscan2
- CCER1 | c.103T>C p.W35R | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as rs1249205856, COSV100727139; called by muse, mutect2
- CD40LG | c.604G>C p.E202Q | Missense Mutation (SNP) | VAF 38/409 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as CM962551, COSV101033542; called by muse, mutect2
- CDC45 | c.1004_1006del p.S335del | In Frame Del (DEL) | VAF 6/65 reads (9%) | catalogued as rs762283906; called by mutect2, pindel
- CDCA7L | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139249411; called by muse, mutect2
- CDH26 | c.2344C>T p.H782Y (on ENST00000348616 / NM_177980.4; = p.H115Y on NM_021810.6) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.461); catalogued as COSV99722905; called by muse, mutect2
- CDH8 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.43); catalogued as COSV100183866, COSV54901521; called by muse, mutect2
- CDK5RAP2 | c.1840G>A p.E614K | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.552); catalogued as rs764066941, COSV62578296; called by muse, mutect2, varscan2
- CENPE | c.6410G>A p.R2137K | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV54376998; called by muse, mutect2
- CEP192 | c.6329C>T p.S2110F | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV58071743; called by muse, mutect2
- CHAC2 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as COSV99712431; called by muse, mutect2
- CHST6 | c.193G>C p.D65H | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100178585, COSV60000809; called by muse, mutect2
- CMTM2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.932); catalogued as rs1465045231, COSV99216573; called by muse, mutect2
- CNGA4 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV101171860, COSV66006493; called by muse, mutect2
- CPA2 | c.291C>G p.V97= | Splice Region (SNP) | VAF 11/93 reads (12%) | catalogued as COSV99744248; called by muse, mutect2, varscan2
- CPEB4 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV99437595; called by muse, mutect2
- CPT1A | c.1313G>A p.S438N | Missense Mutation (SNP) | VAF 10/217 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV99681551; called by muse, mutect2
- CSMD3 | c.7939G>T p.D2647Y (on ENST00000297405 / NM_001363185.1; = p.D2543Y on NM_052900.3) | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99819929; called by muse, mutect2
- CTBP2 | c.667G>A p.V223M | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.149); catalogued as rs76203768, COSV58332067; called by muse, mutect2, varscan2
- CTU2 | c.283-1G>T p.X95_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | catalogued as COSV99966499; called by muse, mutect2
- CUBN | c.7273A>G p.T2425A | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV100913411; called by muse, mutect2
- CUL1 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV57392513; called by muse, mutect2, varscan2
- CYBB | c.542T>C p.V181A | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as COSV101059814; called by muse, mutect2
- DAZAP2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV101199443; called by muse, mutect2
- DEDD2 | c.458del p.P153Qfs*42 | Frame Shift Del (DEL) | VAF 7/38 reads (18%) | catalogued as rs758890887, COSV60141885; called by mutect2, pindel
- DENND2A | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99326883; called by mutect2, varscan2
- DENND6A | c.1826G>C p.*609Sext*38 | Nonstop Mutation (SNP) | VAF 11/122 reads (9%) | catalogued as COSV100231609; called by muse, mutect2
- DIAPH1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 9/210 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV99527188; called by muse, mutect2
- DIAPH3 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.23); catalogued as COSV99934364; called by muse, mutect2
- DIDO1 | c.6243G>C p.Q2081H | Missense Mutation (SNP) | VAF 25/275 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV56631678, COSV99826905; called by muse, mutect2
- DIO2 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV101375930, COSV101375958; called by muse, mutect2
- DLG3 | c.2376G>C p.E792D (on ENST00000374360 / NM_021120.4; = p.E487D on NM_020730.3) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.048); catalogued as rs1309068657; called by muse, mutect2
- DMD | c.10879A>G p.M3627V | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.242); catalogued as rs886044628, COSV100629006; ClinVar: uncertain significance; called by muse, mutect2
- DNAH2 | c.8183C>G p.S2728C | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as COSV101209557; called by muse, mutect2
- DNAH8 | c.11615G>A p.R3872H | Missense Mutation (SNP) | VAF 17/171 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs374402427, COSV59474082, COSV59488984; called by muse, mutect2, varscan2
- DNAH9 | c.13455G>C p.Q4485H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99307738; called by muse, mutect2
- DNM2 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100117022, COSV100117875; called by muse, mutect2, varscan2
- DNMBP | c.1454C>G p.S485* | Nonsense Mutation (SNP) | VAF 7/135 reads (5%) | catalogued as COSV100144347; called by muse, mutect2
- DOCK11 | c.3550C>G p.R1184G | Missense Mutation (SNP) | VAF 21/230 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as COSV52239482, COSV99354591; called by muse, mutect2
- DYRK1B | c.1633del p.Q545Sfs*19 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | catalogued as rs775499198; called by mutect2, pindel, varscan2
- E4F1 | c.1054G>T p.E352* | Nonsense Mutation (SNP) | VAF 11/105 reads (10%) | catalogued as COSV100066054; called by muse, mutect2, varscan2
- EEFSEC | c.1147G>T p.D383Y | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV54623823, COSV99631230; called by muse, mutect2
- EIF2B3 | c.1009G>C p.E337Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.127); catalogued as COSV100838983, COSV64517456; called by muse, mutect2
- EIF4B | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs776635410, COSV100016970; called by muse, mutect2
- EPB41L1 | c.2483T>A p.I828N | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52433989, COSV99151525; called by muse, mutect2
- ESYT2 | c.1306C>G p.P436A (on ENST00000613624; = p.P360A on NM_020728.3) | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99277196; called by muse, mutect2
- EXPH5 | c.1593A>T p.E531D | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.535); catalogued as COSV99762085; called by muse, mutect2, varscan2
- FAM110B | c.331G>A p.V111M | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.479); catalogued as rs766614164, COSV64063152; called by mutect2, varscan2
- FAM135A | c.2996del p.N999Ifs*5 (on ENST00000370479 / NM_001351599.1; = p.N786Ifs*5 on NM_020819.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | catalogued as rs780725577; called by mutect2, varscan2
- FAM155A | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 8/135 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.437); catalogued as COSV101029950; called by muse, mutect2
- FAM71C | c.408del p.K136Nfs*5 | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | catalogued as rs762930877; called by mutect2, pindel, varscan2
- FANCM | c.4005del p.V1336Lfs*2 | Frame Shift Del (DEL) | VAF 12/89 reads (13%) | catalogued as rs746983128; called by mutect2, varscan2
- FASTKD1 | c.62T>G p.I21S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV101328539; called by muse, mutect2, varscan2
- FAT1 | c.10058C>T p.S3353F | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.815); catalogued as COSV101499611; called by muse, mutect2, varscan2
- FAT4 | c.6569G>A p.R2190H | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs182837803, COSV58715427; called by muse, mutect2
- FBN2 | c.4091G>A p.G1364E | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99330215; called by muse, mutect2, varscan2
- FHOD1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.049); catalogued as rs372756034; called by muse, mutect2, varscan2
- FLNA | c.7679T>C p.V2560A (on ENST00000369850 / NM_001110556.2; = p.V2552A on NM_001456.3) | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100775133; called by muse, mutect2
- FRMPD4 | c.1975G>A p.A659T | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.009); catalogued as rs760858730, COSV101043886; called by muse, mutect2
- FSD2 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100575271; called by muse, mutect2
- G6PC2 | c.153G>C p.Q51H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV99960878; called by muse, mutect2, varscan2
- GAL3ST4 | c.530C>T p.S177L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV100385621; called by muse, mutect2
- GALNT1 | c.947G>A p.W316* | Nonsense Mutation (SNP) | VAF 8/98 reads (8%) | catalogued as rs1212120054, COSV99322480; called by muse, mutect2
- GALNT16 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100546158; called by muse, mutect2
- GBX2 | c.781G>C p.E261Q | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100103602; called by muse, mutect2
- GIPC3 | c.281del p.G94Vfs*3 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | catalogued as rs750147424; called by mutect2, pindel, varscan2
- GLI3 | c.1673C>G p.S558W | Missense Mutation (SNP) | VAF 8/102 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67888467; called by muse, mutect2
- GLRA4 | c.347C>A p.S116Y | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV101009706; called by muse, mutect2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 13/104 reads (13%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GSDME | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 23/184 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100742431; called by muse, mutect2, varscan2
- GXYLT2 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101274664; called by mutect2, varscan2
- GYG2 | c.1163C>T p.A388V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.081); catalogued as COSV100089242; called by muse, mutect2, varscan2
- H2AZ1 | c.338A>G p.H113R | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as COSV99597578; called by muse, mutect2
- HCN1 | c.1960A>G p.T654A | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100301972; called by muse, mutect2, varscan2
- HEPH | c.1366C>A p.L456M (on ENST00000343002; = p.L189M on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV100293876, COSV57964188; called by muse, mutect2
- HOXC13 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54499256; called by muse, mutect2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as rs770632206; called by mutect2, varscan2
- HRH1 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 20/197 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415881003, COSV101229103; called by muse, mutect2
- HTR1B | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV100885466; called by muse, mutect2, varscan2
- HTRA2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 19/339 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.627); catalogued as rs142306682; called by muse, mutect2
- IFT172 | c.2238G>A p.W746* | Nonsense Mutation (SNP) | VAF 9/147 reads (6%) | catalogued as rs1393583850, COSV99563169; called by muse, mutect2
- IGF2R | c.4960G>A p.V1654M | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773729117, COSV100808061; called by mutect2, varscan2
- IGFBP3 | c.666T>A p.N222K | Missense Mutation (SNP) | VAF 13/145 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); catalogued as COSV99298496; called by muse, mutect2
- IGHMBP2 | c.2294A>G p.H765R | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV99662499; called by muse, mutect2
- IGSF1 | c.2975G>A p.R992Q | Missense Mutation (SNP) | VAF 19/192 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63837491, COSV63839716; called by muse, mutect2
- IKZF3 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs891247136, COSV53101304; called by muse, mutect2
- IRGQ | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs372119753; called by muse, mutect2, varscan2
- ITGA1 | c.1950T>A p.D650E | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV50886335; called by muse, mutect2
- ITGA4 | c.1100G>A p.R367K | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99276755; called by muse, mutect2, varscan2
- ITPKB | c.2272A>G p.K758E | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99685083; called by muse, mutect2
- ITPKB | c.718C>T p.R240W | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99685085; called by muse, mutect2
- JAKMIP3 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV100059819; called by muse, mutect2
- JPH1 | c.683C>A p.S228Y | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV100646757; called by muse, mutect2
- KALRN | c.7231C>T p.R2411W (on ENST00000360013 / NM_001024660.4; = p.R714W on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1010276863, COSV99362796; called by muse, mutect2, varscan2
- KCNA2 | c.509T>C p.V170A | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100316102; called by muse, mutect2, varscan2
- KCNA3 | c.1402G>A p.G468S | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901499; called by muse, mutect2, varscan2
- KCNG2 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100301708; called by muse, mutect2
- KCNH5 | c.2606C>A p.T869K | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); catalogued as COSV100527877; called by muse, mutect2
- KCNJ10 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.074); catalogued as COSV100927953, COSV63633656; called by muse, mutect2
- KIF21A | c.1915G>C p.E639Q (on ENST00000361418 / NM_001378440.1; = p.E626Q on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100735613; called by muse, mutect2, varscan2
- KLHL9 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100757158; called by muse, mutect2
- KMT2C | c.4794-1G>T p.X1598_splice | Splice Site (SNP) | VAF 11/107 reads (10%) | catalogued as COSV100074671; called by muse, mutect2
- KNOP1 | c.957del p.G320Afs*8 | Frame Shift Del (DEL) | VAF 10/91 reads (11%) | catalogued as rs759734033, COSV54927684; called by mutect2, varscan2
- KRAS | c.472A>G p.T158A | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV55663749; called by muse, mutect2
- L3MBTL3 | c.508A>G p.S170G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV100696361; called by muse, mutect2, varscan2
- LAG3 | c.1191G>A p.W397* | Nonsense Mutation (SNP) | VAF 9/90 reads (10%) | catalogued as rs61731925, COSV52568222; called by muse, mutect2, varscan2
- LILRA2 | c.352G>T p.G118* | Nonsense Mutation (SNP) | VAF 8/80 reads (10%) | catalogued as rs1233097088, COSV99253874; called by muse, mutect2
- LPAR6 | c.948C>G p.F316L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.65); PolyPhen benign (0.039); catalogued as rs750415786, COSV57303361, COSV57307458, COSV99926504; called by muse, mutect2, varscan2
- LRP1B | c.4227G>A p.M1409I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV101260064; called by muse, mutect2
- LRTM1 | c.539A>G p.N180S | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1197377310, COSV99836196; called by muse, mutect2
- MAGEC2 | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.465); catalogued as COSV99909873; called by muse, mutect2
- MAP2 | c.4747C>T p.R1583C | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760779247, COSV52283134, COSV52288569; called by muse, mutect2, varscan2
- MAP3K5 | c.2930G>C p.S977T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.952); catalogued as COSV100753205, COSV62890617; called by muse, mutect2
- MAPKAPK3 | c.782G>A p.G261D | Missense Mutation (SNP) | VAF 11/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100781773; called by muse, mutect2
- MAPKBP1 | c.328-1G>A p.X110_splice | Splice Site (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99530078; called by muse, mutect2
- MAST1 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV99263586; called by muse, mutect2
- MB21D2 | c.647del p.N216Mfs*11 | Frame Shift Del (DEL) | VAF 9/104 reads (9%) | catalogued as rs748185381; called by mutect2, pindel
- MCM3AP | c.4319C>T p.A1440V | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs771441002, COSV52438014; called by muse, mutect2
- MGAT4C | c.894G>C p.Q298H | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100153305; called by muse, mutect2, varscan2
- MIA2 | c.1266C>A p.S422R | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as COSV99698132; called by muse, mutect2
- MPDZ | c.5106G>C p.Q1702H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs959095849, COSV59923927; called by muse, mutect2
- MRM1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs781242447; called by muse, mutect2, varscan2
- MROH2B | c.2501G>A p.R834Q | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.928); catalogued as rs199943039, COSV101270893; called by muse, mutect2, varscan2
- MRPL17 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99996921; called by muse, mutect2
- MRPL37 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.984); catalogued as rs1212016201, COSV100289393; called by muse, mutect2, varscan2
- MRPS24 | c.253C>T p.R85* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs776963478, COSV58183377; called by muse, mutect2, varscan2
- MTA1 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs782517455, COSV58755926, COSV58756822; called by muse, mutect2
- MUC16 | c.42668A>G p.Y14223C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV101110065; called by muse, mutect2, varscan2
- MYH2 | c.4058A>G p.Y1353C | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1413745380, COSV99820826; called by muse, mutect2, varscan2
- MYH3 | c.3376G>A p.E1126K | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99878756; called by muse, mutect2, varscan2
- MYLK3 | c.280C>A p.L94M | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101189190; called by muse, mutect2
- MYRF | c.871C>T p.R291* (on ENST00000278836 / NM_001127392.3; = p.R282* on NM_013279.4) | Nonsense Mutation (SNP) | VAF 12/158 reads (8%) | catalogued as COSV99607765; called by muse, mutect2
- N4BP2L2 | c.2618T>C p.I873T (on ENST00000674422; = p.I444T on NM_033111.4) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.144); catalogued as COSV100679282; called by muse, mutect2, varscan2
- NCKAP1L | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.83); catalogued as COSV53205016; called by muse, mutect2
- NCOA1 | c.2913G>C p.E971D | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV56047948; called by muse, mutect2, varscan2
- NEXMIF | c.3579G>C p.Q1193H | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV99281667; called by muse, mutect2
- NFE2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.129); catalogued as COSV100380847; called by muse, mutect2
- NGDN | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV68143280; called by muse, mutect2, varscan2
- NIPBL | c.4687G>C p.E1563Q | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99242333; called by muse, mutect2
- NLRP5 | c.3452C>G p.S1151C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as COSV66762010; called by muse, mutect2
- NOL4 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 15/186 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs137958344; called by muse, mutect2
- NOTCH1 | c.5533C>T p.Q1845* | Nonsense Mutation (SNP) | VAF 4/51 reads (8%) | catalogued as COSV53085817; called by muse, mutect2
- NPY | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV99636028; called by muse, mutect2
- NR2E1 | c.151G>T p.V51F | Missense Mutation (SNP) | VAF 15/176 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV100934622; called by muse, mutect2
- NUTM1 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV100149184; called by muse, mutect2, varscan2
- NUTM2F | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs1010354406, COSV53556594; called by muse, mutect2
- OBSCN | c.5740G>A p.G1914S | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1469330443, COSV99483454; called by muse, mutect2
- OLFML2B | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs762138844, COSV99668838; called by muse, mutect2, varscan2
- OR2J2 | c.144C>G p.I48M | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as rs1024063695, COSV101013447; called by muse, mutect2
- OTUD6B | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1008311775, COSV99576056; called by muse, mutect2, varscan2
- PARP4 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 8/61 reads (13%) | catalogued as COSV101132003; called by muse, mutect2, varscan2
- PCDH1 | c.3389C>G p.S1130C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746861; called by muse, mutect2, varscan2
- PCDH15 | c.5051C>T p.A1684V (on ENST00000644397 / NM_001354429.2; = p.A1626V on NM_001142771.2) | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as rs752801351, COSV100905466; called by muse, mutect2
- PCDH17 | c.3419G>C p.R1140T | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV100931931, COSV64973889; called by muse, mutect2
- PCDHA12 | c.1781T>C p.V594A | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV100253803; called by muse, mutect2
- PCDHB14 | c.1492C>A p.L498M | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53391801; called by muse, mutect2
- PCDHGA5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV54027796; called by muse, mutect2
- PCDHGB1 | c.1367A>G p.H456R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV99545603; called by muse, mutect2
- PCED1A | c.1269del p.C425Afs*11 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | catalogued as rs772305388; called by mutect2, pindel
- PCNX1 | c.1175A>T p.D392V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1215216802; called by muse, mutect2
- PDCD2L | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 17/170 reads (10%) | catalogued as rs767147956, COSV99875131; called by muse, mutect2
- PDE5A | c.1819C>T p.R607W | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1265376573, COSV53347874; called by muse, mutect2
- PDGFD | c.727A>T p.T243S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100160591; called by muse, mutect2, varscan2
- PDGFD | c.599T>C p.V200A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as COSV100160593; called by muse, mutect2, varscan2
- PHOSPHO2 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV99776098; called by muse, mutect2, varscan2
- PI3 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs541768512, COSV54783528; called by muse, mutect2, varscan2
- PIK3C2G | c.192dup p.V65Cfs*16 | Frame Shift Ins (INS) | VAF 11/90 reads (12%) | catalogued as rs1565550462; called by mutect2, pindel, varscan2
- PKD1L1 | c.4035G>C p.W1345C | Missense Mutation (SNP) | VAF 11/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99219433, COSV99221153; called by muse, mutect2
- PLEKHG2 | c.1360C>G p.R454G | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as COSV99218007; called by muse, mutect2, varscan2
- PPFIA4 | c.2249G>A p.R750H (on ENST00000447715; = p.R751H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV99690709; called by muse, mutect2
- PREX1 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as rs375685234; called by muse, mutect2
- PREX2 | c.4379C>G p.P1460R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.093); catalogued as COSV99909545; called by muse, mutect2, varscan2
- PRH2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.803); catalogued as COSV101113340; called by muse, mutect2
- PRKDC | c.10557A>T p.E3519D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.156); catalogued as COSV100042508; called by muse, mutect2
- PRPS1 | c.486G>T p.W162C | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV100978889; called by muse, mutect2
- PRX | c.2310G>T p.K770N | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV99398008; called by muse, mutect2, varscan2
- PSD3 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 6/150 reads (4%) | catalogued as rs1023312684, COSV100497133, COSV58967511; called by muse, mutect2
- PSMC2 | c.226G>C p.A76P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.391); catalogued as COSV99485435; called by muse, mutect2
- PVR | c.566C>T p.T189M | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs561763868, COSV51822280; called by muse, mutect2, varscan2
- RAC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.922); catalogued as COSV61821605; called by muse, mutect2, varscan2
- RALGAPA1 | c.3601del p.S1201Hfs*16 | Frame Shift Del (DEL) | VAF 5/39 reads (13%) | catalogued as rs772197415; called by mutect2, varscan2
- RANBP2 | c.6196G>A p.E2066K | Missense Mutation (SNP) | VAF 41/543 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.111); catalogued as rs997071131, COSV99313077; called by muse, mutect2
- RBM6 | c.1222G>A p.D408N | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56488414; called by muse, mutect2
- RDH16 | c.570C>T p.L190= | Splice Region (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100660162, COSV62458757; called by muse, mutect2, varscan2
- RECK | c.809C>G p.S270C | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV100937623, COSV65035151; called by muse, mutect2, varscan2
- RELN | c.8822A>T p.D2941V | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100634707; called by muse, mutect2, varscan2
- RERE | c.2309C>T p.A770V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100557191; called by muse, mutect2
- RERE | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as rs749986387, COSV61936764; called by muse, mutect2, varscan2
- RMDN1 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as COSV99548032; called by muse, mutect2
- RMDN2 | c.637G>A p.E213K (on ENST00000354545 / NM_001322212.2; = p.E391K on NM_144713.5) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.061); catalogued as COSV52224257; called by muse, mutect2, varscan2
- RPL10L | c.304A>G p.M102V | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs954848812, COSV100022731, COSV53560925; called by muse, mutect2
- RPRML | c.294G>C p.M98I | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV100462004; called by muse, mutect2, varscan2
- RTKN | c.1666C>T p.R556C (on ENST00000272430 / NM_001015055.2; = p.R543C on NM_033046.2) | Missense Mutation (SNP) | VAF 13/215 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.23); catalogued as rs1253780029, COSV51961727; called by muse, mutect2
- RTP3 | c.642C>G p.F214L | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99946981; called by muse, mutect2
- SASH1 | c.1883G>A p.R628Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as rs765106943, COSV66559747, COSV66563748; called by muse, mutect2
- SAXO2 | c.1150G>T p.G384C | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100255890, COSV59754183; called by muse, mutect2
- SBNO1 | c.237G>T p.R79S | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.055); catalogued as COSV57347701; called by muse, mutect2
- SCAF11 | c.1192G>C p.E398Q | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV101014608; called by muse, mutect2
- SCN3A | c.4961C>T p.A1654V | Missense Mutation (SNP) | VAF 7/184 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51801173; called by muse, mutect2
- SEC63 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.076); catalogued as COSV100938464; called by muse, mutect2, varscan2
- SEMG2 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.708); catalogued as COSV101034221; called by muse, mutect2
- SIGLEC11 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.842); catalogued as COSV101389598; called by muse, mutect2, varscan2
- SIK3 | c.2617C>T p.R873C (on ENST00000445177 / NM_001366686.2; = p.R831C on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as rs768087803, COSV52608420; called by mutect2, varscan2
- SLC12A8 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100101974, COSV100103067; called by muse, mutect2
- SLC13A2 | c.959G>T p.R320M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV58995179; called by muse, mutect2, varscan2
- SLC17A4 | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV100930652; called by muse, mutect2
- SLC27A4 | c.28del p.V10Cfs*9 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as COSV100056591; called by mutect2, varscan2
- SLC35E4 | c.586A>G p.T196A | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100299299; called by muse, mutect2, varscan2
- SLC38A5 | c.1015C>T p.R339C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100476738; called by muse, mutect2, varscan2
- SLC45A4 | c.678G>T p.W226C (on ENST00000517878 / NM_001286646.2; = p.W175C on NM_001080431.2) | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as COSV99199712; called by muse, mutect2
- SLC4A11 | c.607G>A p.A203T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.546); catalogued as rs1326467127, COSV66260839; called by muse, mutect2, varscan2
- SLC5A9 | c.1293-1G>A p.X431_splice | Splice Site (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99361933; called by muse, mutect2
- SOCS6 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.019); catalogued as rs868199125, COSV67547084, COSV67547485; called by muse, mutect2, varscan2
- SOWAHB | c.1232G>T p.G411V | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV100530783; called by muse, mutect2, varscan2
- SPAG17 | c.5627C>T p.T1876I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs1557871008, COSV100310170, COSV100310302; called by muse, mutect2, varscan2
- SPATA16 | c.1261G>C p.D421H | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100651563; called by muse, mutect2
- SPHKAP | c.2407G>T p.G803C | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.023); catalogued as COSV100764298; called by muse, mutect2, varscan2
- SPTBN1 | c.2613G>A p.W871* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as COSV100443307; called by muse, mutect2, varscan2
- SQOR | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52943629, COSV99526106; called by muse, mutect2, varscan2
- STRADB | c.661G>C p.D221H | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99524759; called by muse, mutect2, varscan2
- STT3B | c.1708G>A p.A570T | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.834); catalogued as COSV99854502; called by muse, mutect2
- STXBP5L | c.1903G>C p.D635H | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV99876110; called by muse, mutect2
- SVEP1 | c.1262T>C p.L421P | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as COSV100238901; called by muse, mutect2, varscan2
- SYNE1 | c.3833A>G p.H1278R (on ENST00000367255 / NM_182961.4; = p.H1285R on NM_033071.3) | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV99576244; called by muse, mutect2
- SYNE1 | c.2755A>G p.K919E (on ENST00000367255 / NM_182961.4; = p.K926E on NM_033071.3) | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV99576247; called by muse, mutect2
- SYNE1 | c.736G>A p.A246T (on ENST00000367255 / NM_182961.4; = p.A253T on NM_033071.3) | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as rs1251834592, COSV55002960; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TAF2 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100978785; called by muse, mutect2
- TBX20 | c.749A>G p.E250G | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.9); catalogued as COSV101282415; called by muse, mutect2
- TENT4B | c.1900C>G p.Q634E (on ENST00000561678 / NM_001365323.2; = p.Q619E on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.051); catalogued as COSV100666156, COSV62549398; called by muse, mutect2
- TIAM1 | c.19C>G p.Q7E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.282); catalogued as COSV99738363; called by muse, mutect2, varscan2
- TKTL2 | c.22C>T p.P8S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99761699; called by muse, mutect2
- TLR10 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100458006; called by muse, mutect2
- TM9SF3 | c.214del p.S72Vfs*31 | Frame Shift Del (DEL) | VAF 18/144 reads (13%) | catalogued as rs760930120; called by mutect2, varscan2
- TMED3 | c.367G>C p.E123Q | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.145); catalogued as COSV100230058; called by muse, mutect2
- TMEM131 | c.3979G>A p.A1327T | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1221515381, COSV99489368; called by muse, mutect2
- TMEM131L | c.2003C>T p.S668F | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99548047; called by muse, mutect2
- TMEM147 | c.294G>C p.K98N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV52868394; called by muse, mutect2
- TMEM178A | c.575G>A p.C192Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.114); catalogued as COSV99932037; called by muse, mutect2
- TMEM260 | c.1399-1G>C p.X467_splice | Splice Site (SNP) | VAF 7/103 reads (7%) | catalogued as COSV99840615; called by muse, mutect2
- TNPO2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.248); catalogued as COSV100790407; called by muse, mutect2
- TOP1MT | c.1356C>G p.I452M | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.375); catalogued as COSV100239667; called by muse, mutect2
- TOP3A | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58175050; called by muse, mutect2
- TP53BP1 | c.3755G>A p.R1252H | Missense Mutation (SNP) | VAF 13/167 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1305202353, COSV99781360; called by muse, mutect2
- TPCN1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769047690, COSV100137026; called by muse, mutect2, varscan2
- TPCN2 | c.1418A>G p.N473S | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as COSV99593886; called by muse, mutect2
- TRPM7 | c.1057del p.T353Hfs*16 | Frame Shift Del (DEL) | VAF 6/71 reads (8%) | catalogued as rs1177791755; called by pindel, varscan2
- TTC26 | c.1658C>A p.S553Y | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100571145; called by muse, mutect2
- TTC36 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 15/246 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs1421512085, COSV57096719; called by muse, mutect2
- TUSC3 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 5/96 reads (5%) | catalogued as rs868472774, COSV101140155; called by muse, mutect2
- UBQLN3 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV100293939; called by muse, mutect2
- UCK1 | c.620A>G p.D207G | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100586557; called by muse, mutect2
- UGGT1 | c.3667G>C p.D1223H | Missense Mutation (SNP) | VAF 9/159 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV52135128, COSV99391090; called by muse, mutect2
- USH2A | c.10270A>G p.I3424V | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100241412; called by muse, mutect2
- USP17L2 | c.1576C>G p.L526V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV100414708; called by muse, mutect2
- USP24 | c.6076G>A p.D2026N | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV99600815; called by muse, mutect2
- USP32 | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100342726; called by muse, mutect2, varscan2
- USP45 | c.1420A>G p.S474G | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV100569905; called by muse, mutect2, varscan2
- USP9X | c.5884G>C p.D1962H | Missense Mutation (SNP) | VAF 15/167 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as COSV100200010; called by muse, mutect2
- VCAN | c.9487G>A p.E3163K | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99427085; called by muse, mutect2, varscan2
- VCP | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100734339; called by muse, mutect2
- VPS35 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV54481377; called by muse, mutect2
- VPS41 | c.1163del p.N388Ifs*15 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs757692785; called by mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | catalogued as rs762079039; called by mutect2, pindel, varscan2
- XIRP2 | c.2554G>A p.D852N (on ENST00000628543; = p.D1027N on NM_152381.6) | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54731630; called by muse, mutect2
- XKR4 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1250153684, COSV59342741; called by muse, mutect2
- ZFYVE26 | c.850A>G p.T284A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV100720691; called by mutect2, varscan2
- ZG16B | c.178G>T p.G60* | Nonsense Mutation (SNP) | VAF 20/250 reads (8%) | catalogued as COSV101206769; called by muse, mutect2
- ZHX1 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99933846; called by muse, mutect2
- ZHX1 | c.566A>G p.N189S | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99933848; called by muse, mutect2
- ZMIZ1 | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | catalogued as COSV100565934; called by muse, mutect2
- ZMYM3 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs1376678421, COSV100078329; called by muse, mutect2, varscan2
- ZNF124 | c.1015del p.T339Lfs*31 (on ENST00000543802 / NM_001297568.1; = p.T277Lfs*31 on NM_003431.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/65 reads (12%) | catalogued as COSV61506988; called by mutect2, pindel, varscan2
- ZNF214 | c.1774G>C p.D592H | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV99547622; called by muse, mutect2, varscan2
- ZNF217 | c.3146G>C p.*1049Sext*4 | Nonstop Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100184768; called by muse, mutect2
- ZNF266 | c.1120C>G p.H374D | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100749437; called by muse, mutect2
- ZNF439 | c.713G>C p.G238A | Missense Mutation (SNP) | VAF 16/149 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.29); catalogued as rs569672688, COSV100397547; called by muse, mutect2, varscan2
- ZNF543 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100386909; called by muse, mutect2
- ZNF600 | c.610T>C p.Y204H | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV100593090; called by muse, mutect2
- ZNF618 | c.1800G>C p.Q600H (on ENST00000374126 / NM_001318042.2; = p.Q507H on NM_133374.2) | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99930957; called by muse, mutect2, varscan2
- ZNF721 | c.743C>T p.S248L (on ENST00000338977; = p.S260L on NM_133474.4) | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.966); catalogued as COSV100167735; called by muse, mutect2
- ZNF74 | c.1898G>A p.G633D | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV100677535, COSV99051680; called by muse, mutect2, varscan2
- ZNF786 | c.2328G>C p.M776I | Missense Mutation (SNP) | VAF 22/320 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100302979; called by muse, mutect2
- ZNF792 | c.1240A>G p.R414G | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101289748; called by muse, mutect2, varscan2
- AHNAK | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 8/193 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.375); called by muse, mutect2
- ARHGAP35 | c.2834del p.K945Rfs*3 | Frame Shift Del (DEL) | VAF 16/154 reads (10%) | called by mutect2, pindel
- BSN | c.8296dup p.L2766Pfs*50 | Frame Shift Ins (INS) | VAF 9/78 reads (12%) | called by mutect2, pindel, varscan2
- CCDC77 | c.1444G>C p.E482Q | Missense Mutation (SNP) | VAF 8/173 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CDAN1 | c.2617A>C p.I873L | Missense Mutation (SNP) | VAF 4/94 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.183); called by muse, mutect2
- EHD2 | c.1235del p.G412Afs*35 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- EPHA2 | c.1379del p.P460Rfs*33 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | called by mutect2, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by mutect2, varscan2
- GIPR | c.1011G>A p.L337= | Splice Region (SNP) | VAF 4/75 reads (5%) | called by muse, mutect2
- HNRNPDL | c.338del p.P113Lfs*11 | Frame Shift Del (DEL) | VAF 10/108 reads (9%) | called by mutect2, pindel
- KALRN | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.22); called by muse, mutect2
- LARP1B | c.2258del p.M753Sfs*21 | Frame Shift Del (DEL) | VAF 5/61 reads (8%) | called by mutect2, pindel
- MOGAT2 | c.203del p.G68Afs*16 | Frame Shift Del (DEL) | VAF 23/196 reads (12%) | called by mutect2, pindel, varscan2
- NUP205 | c.179del p.N60Mfs*70 | Frame Shift Del (DEL) | VAF 7/67 reads (10%) | called by mutect2, pindel
- ORC5 | c.419G>C p.G140A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PHF13 | c.413del p.G138Afs*3 | Frame Shift Del (DEL) | VAF 12/60 reads (20%) | called by mutect2, pindel, varscan2
- PITPNM1 | c.360del p.Q121Sfs*8 | Frame Shift Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- PMEL | c.123_135del p.K42Gfs*32 | Frame Shift Del (DEL) | VAF 14/167 reads (8%) | called by mutect2, pindel
- POC1B-GALNT4 | c.1287del p.P430Lfs*26 | Frame Shift Del (DEL) | VAF 9/105 reads (9%) | called by mutect2, pindel
- PRCC | c.1138del p.Q380Rfs*47 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, varscan2
- PTN | c.123del p.V42* | Frame Shift Del (DEL) | VAF 5/28 reads (18%) | called by mutect2, varscan2
- SPATA31A1 | c.3924C>G p.I1308M | Missense Mutation (SNP) | VAF 19/290 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.031); called by muse, mutect2
- SSH2 | c.1959del p.F653Lfs*4 | Frame Shift Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel, varscan2
- TANC1 | c.3539C>G p.S1180* | Nonsense Mutation (SNP) | VAF 4/82 reads (5%) | called by muse, mutect2
- TEDC2 | c.978G>T p.Q326H | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- TENM1 | c.367dup p.M123Nfs*11 | Frame Shift Ins (INS) | VAF 39/323 reads (12%) | called by mutect2, pindel, varscan2
- TTLL3 | c.1110del p.E371Rfs*44 | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | called by mutect2, pindel, varscan2
- UBN2 | c.1745del p.N582Mfs*16 | Frame Shift Del (DEL) | VAF 8/82 reads (10%) | called by mutect2, pindel
- AADACL3 | c.597C>A p.A199= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV100206849; called by muse, mutect2
- ABCC1 | c.267C>G p.L89= | Silent (SNP) | VAF 22/173 reads (13%) | catalogued as COSV100580259, COSV60691305; called by muse, mutect2, varscan2
- AC104452.1 | c.1303C>T p.L435= | Silent (SNP) | VAF 15/134 reads (11%) | catalogued as COSV99648696; called by muse, mutect2, varscan2
- ADGRG5 | c.342C>A p.P114= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV100446467; called by muse, mutect2, varscan2
- ADI1 | c.324G>A p.R108= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV100537825; called by muse, mutect2
- AHNAK | c.708C>G p.L236= | Silent (SNP) | VAF 7/114 reads (6%) | catalogued as COSV99949299; called by muse, mutect2
- AUP1 | c.192C>T p.F64= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99239910; called by mutect2, varscan2
- BAHD1 | c.1752T>C p.R584= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as rs762888298, COSV69084048; called by muse, varscan2
- BMP4 | c.90G>A p.T30= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs773605577, COSV55415101, COSV55416601; called by muse, mutect2, varscan2
- C15orf40 | c.186C>T p.C62= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs1264761052, COSV58449250; called by muse, mutect2
- CAND1 | c.1833A>G p.T611= | Silent (SNP) | VAF 9/241 reads (4%) | called by muse, mutect2
- CARM1 | c.1152C>T p.V384= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99450297; called by muse, mutect2
- CCDC65 | c.1008G>C p.L336= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV99872809, COSV99872871; called by muse, mutect2, varscan2
- CDH9 | c.594C>G p.V198= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99151466; called by muse, mutect2
- CHST5 | c.1074G>A p.A358= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs764453614, COSV100292113; called by muse, mutect2
- CLMN | c.1113G>A p.A371= | Silent (SNP) | VAF 10/99 reads (10%) | catalogued as rs753946996, COSV54183061; called by muse, mutect2, varscan2
- COL16A1 | c.483C>A p.P161= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV99595304; called by muse, mutect2, varscan2
- COL26A1 | c.234C>T p.R78= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs376211020; called by muse, varscan2
- CTTNBP2 | c.3660C>T p.S1220= | Silent (SNP) | VAF 6/95 reads (6%) | catalogued as COSV50390079, COSV99354714; called by muse, mutect2
- EGFLAM | c.1902C>T p.F634= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV59295987; called by muse, mutect2, varscan2
- ELN | c.201C>T p.P67= | Silent (SNP) | VAF 30/330 reads (9%) | catalogued as rs782698181, COSV99333062; called by muse, mutect2
- ENPP2 | c.2457C>G p.L819= (on ENST00000075322 / NM_001040092.3; = p.L871= on NM_006209.5) | Silent (SNP) | VAF 15/160 reads (9%) | catalogued as COSV99309235; called by muse, mutect2
- ESPL1 | c.3918G>A p.E1306= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV99229710; called by muse, mutect2
- FAM166A | c.909G>C p.R303= | Silent (SNP) | VAF 11/211 reads (5%) | catalogued as COSV100458150; called by muse, mutect2
- FAM47C | c.1518C>T p.R506= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as rs149060980, COSV63723690; called by muse, mutect2
- FANCD2OS | c.288C>T p.L96= | Silent (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99812282; called by muse, mutect2
- FCGRT | c.177G>C p.L59= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV99675346; called by muse, mutect2
- FRMPD3 | c.4128C>G p.L1376= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV99346948; called by muse, mutect2, varscan2
- GCM1 | c.225C>A p.S75= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV99452610; called by muse, mutect2
- GON4L | c.2286G>T p.L762= | Silent (SNP) | VAF 6/87 reads (7%) | catalogued as COSV99673955, COSV99675580; called by muse, mutect2
- GPR37 | c.1782G>A p.S594= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as rs374455144; called by muse, mutect2, varscan2
- GPR83 | c.909C>G p.L303= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV54717652, COSV99703777; called by muse, mutect2
- GTF3C1 | c.939C>T p.I313= | Silent (SNP) | VAF 16/144 reads (11%) | catalogued as COSV100649661; called by muse, mutect2, varscan2
- HERC1 | c.3525G>A p.T1175= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as rs1314083175, COSV101496375; called by muse, mutect2
- HS3ST1 | c.591C>T p.H197= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs138931078, COSV50023504; called by mutect2, varscan2
- IFT140 | c.199C>T p.L67= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as COSV68486740; called by muse, mutect2
- ITIH2 | c.942C>T p.V314= | Silent (SNP) | VAF 8/90 reads (9%) | catalogued as rs1388892519, COSV100623390; called by muse, mutect2
- KBTBD13 | c.1254C>T p.G418= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs1258836903, COSV101416703; called by muse, mutect2
- KCNH5 | c.2745C>T p.H915= | Silent (SNP) | VAF 13/167 reads (8%) | catalogued as rs138093802; called by muse, mutect2
- KIAA1614 | c.741C>T p.G247= | Silent (SNP) | VAF 17/215 reads (8%) | catalogued as rs374668814; called by muse, mutect2
- KLF5 | c.288G>C p.L96= | Silent (SNP) | VAF 13/147 reads (9%) | catalogued as COSV66615629; called by muse, mutect2
- KRTAP5-8 | c.36C>T p.S12= | Silent (SNP) | VAF 16/160 reads (10%) | catalogued as rs774662757, COSV68324906; called by muse, mutect2
- LAIR2 | c.15C>T p.L5= | Silent (SNP) | VAF 4/90 reads (4%) | called by muse, mutect2
- LARP1B | c.1455T>C p.N485= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV99218850; called by muse, mutect2, varscan2
- LIG4 | c.1953C>T p.N651= | Silent (SNP) | VAF 13/96 reads (14%) | catalogued as rs780588115, COSV63597241; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAGEA8 | c.552C>T p.C184= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as rs1557370987, COSV99674771; called by muse, mutect2
- MAP3K19 | c.813G>A p.S271= | Silent (SNP) | VAF 20/108 reads (19%) | catalogued as rs772166646, COSV59638066; called by muse, mutect2, varscan2
- MAPKAPK2 | c.144C>G p.V48= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs150764573; called by muse, mutect2
- MARCHF6 | c.2079G>A p.T693= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as rs1436406165; called by muse, mutect2
- MAST3 | c.1458C>T p.I486= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1279061919, COSV99446065; called by muse, mutect2
- MFN1 | c.1341G>A p.K447= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as COSV99764674; called by muse, mutect2
- MID2 | c.507G>A p.T169= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs376601333, COSV53310350; called by muse, mutect2, varscan2
- MRC1 | c.3213C>T p.C1071= | Silent (SNP) | VAF 7/154 reads (5%) | catalogued as rs1405572928; called by muse, mutect2
- MTNR1B | c.718C>T p.L240= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV99925303; called by muse, mutect2, varscan2
- MYO10 | c.3726C>T p.R1242= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV99946140; called by muse, mutect2
- NFATC1 | c.606G>A p.T202= | Silent (SNP) | VAF 12/131 reads (9%) | catalogued as rs146509068; called by muse, mutect2
- NLRP14 | c.1218C>T p.S406= | Silent (SNP) | VAF 15/184 reads (8%) | catalogued as COSV100205367; called by muse, mutect2
- NMD3 | c.1506G>C p.L502= | Silent (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- NPSR1 | c.270G>A p.L90= | Silent (SNP) | VAF 6/76 reads (8%) | catalogued as COSV100707067; called by muse, mutect2
- NUAK1 | c.759C>T p.F253= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs1328215416, COSV99776740; called by muse, mutect2, varscan2
- OR51B6 | c.891T>C p.I297= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100971975, COSV66512318; called by muse, mutect2
- OR6B1 | c.474G>A p.A158= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as rs562215999, COSV68770285; called by muse, mutect2
- ORC5 | c.450A>G p.R150= | Silent (SNP) | VAF 7/92 reads (8%) | catalogued as COSV99857302; called by muse, mutect2
- PCDHA10 | c.690G>C p.L230= | Silent (SNP) | VAF 8/152 reads (5%) | catalogued as COSV100253800; called by muse, mutect2
- PCDHA9 | c.2112C>T p.I704= | Silent (SNP) | VAF 10/102 reads (10%) | catalogued as COSV65325426, COSV65332501; called by muse, mutect2
- PDCD11 | c.1101G>A p.V367= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs778805006, COSV100874408; called by muse, mutect2, varscan2
- PDLIM3 | c.378C>T p.L126= (on ENST00000284770 / NM_001257963.1; = p.L293= on NM_014476.6) | Silent (SNP) | VAF 5/46 reads (11%) | catalogued as rs766386102, COSV99507816; called by muse, mutect2, varscan2
- PEX14 | c.252A>C p.T84= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV100750274; called by muse, mutect2, varscan2
- PI4KA | c.609T>C p.S203= | Silent (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99748297; called by muse, mutect2
- PLEKHA8 | c.837G>A p.L279= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as COSV99322129; called by muse, mutect2, varscan2
- PON3 | c.393G>A p.V131= | Silent (SNP) | VAF 7/116 reads (6%) | catalogued as COSV99672676; called by muse, mutect2
- PSENEN | c.297C>T p.G99= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs148274462; called by muse, mutect2, varscan2
- RACK1 | c.618C>T p.L206= | Silent (SNP) | VAF 8/168 reads (5%) | catalogued as COSV100163477; called by muse, mutect2
- RAP1GAP2 | c.300G>A p.P100= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs755329622, COSV54576143; called by muse, mutect2, varscan2
- RHOD | c.507C>T p.L169= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV58211332; called by muse, mutect2, varscan2
- SCAP | c.1380C>A p.A460= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV99653192; called by muse, mutect2
- SIGLEC10 | c.1755G>A p.R585= | Silent (SNP) | VAF 8/115 reads (7%) | catalogued as COSV100219387; called by muse, mutect2
- SKOR1 | c.234C>T p.G78= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as COSV58248122; called by muse, mutect2
- SLC23A2 | c.1449G>A p.P483= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as rs771231130, COSV100595238; called by muse, mutect2, varscan2
- SLC25A14 | c.357C>A p.T119= | Silent (SNP) | VAF 9/89 reads (10%) | catalogued as COSV99502590; called by muse, mutect2, varscan2
- SLC7A1 | c.630G>A p.V210= | Silent (SNP) | VAF 19/168 reads (11%) | catalogued as COSV101060274; called by muse, mutect2, varscan2
- SMARCA5 | c.1515C>T p.F505= | Silent (SNP) | VAF 7/111 reads (6%) | catalogued as COSV51644528; called by muse, mutect2
- SPHKAP | c.4185C>T p.N1395= | Silent (SNP) | VAF 30/177 reads (17%) | catalogued as COSV100764504; called by muse, mutect2, varscan2
- STOX2 | c.450C>G p.L150= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as COSV100409164; called by muse, mutect2, varscan2
- TACC3 | c.315C>T p.L105= | Silent (SNP) | VAF 31/410 reads (8%) | catalogued as rs1017302815, COSV100508903; called by muse, mutect2
- TAF9B | c.48C>A p.A16= | Silent (SNP) | VAF 10/184 reads (5%) | catalogued as COSV100540755; called by muse, mutect2
- TAGAP | c.429G>A p.A143= | Silent (SNP) | VAF 13/92 reads (14%) | catalogued as rs373228267, COSV100487630; called by muse, mutect2, varscan2
- TBC1D1 | c.504G>A p.T168= | Silent (SNP) | VAF 12/147 reads (8%) | catalogued as rs1482168185, COSV99792042; called by muse, mutect2
- TCAIM | c.555A>G p.R185= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV61239772; called by muse, mutect2, varscan2
- TJP3 | c.2484G>A p.G828= | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs571353377, COSV53661182, COSV99516427; called by mutect2, varscan2
- TMPO | c.591G>A p.V197= | Silent (SNP) | VAF 9/134 reads (7%) | catalogued as COSV99702184; called by muse, mutect2
- TRIM10 | c.1065G>T p.L355= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100939824; called by muse, mutect2, varscan2
- TSHR | c.2058G>A p.Q686= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as COSV53318317, COSV99992644; called by muse, mutect2, varscan2
- WDR59 | c.912G>A p.T304= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as rs534012628, COSV100049678; called by muse, mutect2
- WDR7 | c.3183C>A p.V1061= | Silent (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99590258; called by muse, mutect2
- WWP2 | c.471G>A p.L157= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV100598743; called by muse, mutect2, varscan2
- ZNF311 | c.1947C>T p.L649= | Silent (SNP) | VAF 4/53 reads (8%) | catalogued as COSV65852881; called by muse, mutect2
- ZNF438 | c.1758G>T p.L586= | Silent (SNP) | VAF 14/124 reads (11%) | catalogued as COSV100062582, COSV59201590; called by muse, mutect2
- ZNF468 | c.1026G>T p.L342= | Silent (SNP) | VAF 11/181 reads (6%) | catalogued as COSV99700787; called by muse, mutect2
- AC073310.1 | n.395C>T | RNA (SNP) | VAF 17/178 reads (10%) | called by muse, mutect2
- MACF1 | c.15832-11489A>G | Intron (SNP) | VAF 8/96 reads (8%) | catalogued as COSV99246425; called by muse, mutect2
- MATR3 | c.-379-87C>G | Intron (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100735313; called by muse, mutect2
- MIA2 | chr14:39265413 G>A | 5'Flank (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99698128; called by muse, mutect2
- NCAM1 | c.1826-5538G>A | Intron (SNP) | VAF 11/182 reads (6%) | catalogued as rs782743285, COSV57519796; called by muse, mutect2
- OR52A4P | n.811A>G | RNA (SNP) | VAF 8/70 reads (11%) | catalogued as rs1260060010; called by muse, mutect2, varscan2
- RPL13A | c.402+129C>T | Intron (SNP) | VAF 17/118 reads (14%) | catalogued as rs181440388, COSV52618701; called by muse, mutect2, varscan2
